Gene-level copy-number profile of specimen HCM-CSHL-0084-C25-85B from HCMI case HCM-CSHL-0084-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 73.2 years (26,727 days).
Specimen HCM-CSHL-0084-C25-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4cf100e1-2870-4360-91e5-61e854fdf066.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0084-C25-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,258 have no estimate.
https://portal.gdc.cancer.gov/files/20204a2c-39d5-49d4-9801-477b4b0b0e24

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,009; copy number 2: 9,801; copy number 3: 20,536; copy number 4: 20,740; copy number 5: 4,046; copy number 6: 667; copy number 7: 64; copy number 8: 184; copy number 9: 31; copy number 10: 19; copy number 11: 54; copy number 12: 1; copy number 13: 44; copy number 14: 48; copy number 15: 6; copy number 16: 57; copy number 17: 26; copy number 19: 32.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 318 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,795,407, 1 gene, copy number 11: CFHR3.
- chr8:125,998,994–127,419,050, 15 genes, copy number 17–19 (within-gene range 3–19): AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19.
- chr8:127,686,343–128,187,101, 12 genes, copy number 17 (within-gene range 3–17): CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207.
- chr9:35,406,755–38,147,561, 99 genes, copy number 9–13 (broad region; genes not listed).
- chr17:38,419,280–38,855,670, 26 genes, copy number 9: ARHGAP23, AC244153.1, SRCIN1, AC006449.1, EPOP, MIR4734, AC006449.6, AC006449.2, MLLT6, AC006449.3, MIR4726, AC006449.7, CISD3, RNA5SP440, PCGF2, AC006449.5, PSMB3, RNU6-866P, PIP4K2B, CWC25, MIR4727, C17orf98, RPL23, SNORA21B, SNORA21, AC110749.1.
- chr17:39,057,019–41,734,644, 164 genes, copy number 9–19 (broad region; genes not listed).
- chr21:8,603,547–8,603,984, 1 gene, copy number 11: RPSAP68.

Autosomal genes at a single copy (total copy number 1): 1,137. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
